Somatic mutation profile of tumor specimen C3L-10122-05 (aliquot CPT0546530008) from CPTAC case C3L-10122, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 72.8 years (26,594 days).
Specimen C3L-10122-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4796d7f1-79f2-4b8f-8347-28d22597a211.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-10122-32 (Blood Derived Normal), aliquot CPT0546650006; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2105f34e-0919-4ad7-8a99-73fb70bf8d02

The open-access MAF lists 169 somatic variants for this specimen: 121 protein-altering or splice-affecting, 39 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 39, Nonsense Mutation 9, Intron 4, Frame Shift Ins 3, Frame Shift Del 3, RNA 2, 5'Flank 2, Splice Site 1, In Frame Del 1, Nonstop Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F8 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 65/471 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852380, CM106046, CM960537; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.2446C>T p.R816* | Nonsense Mutation (SNP) | VAF 181/555 reads (33%) | catalogued as rs886041347, CM971040, COSV62196183; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 186/651 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as rs587782705, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABHD2 | c.854G>A p.S285N | Missense Mutation (SNP) | VAF 69/524 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs765464096; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2173C>T p.R725C | Missense Mutation (SNP) | VAF 68/597 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs375869565; called by muse, mutect2, varscan2
- ADGRA2 | c.2572C>T p.R858* | Nonsense Mutation (SNP) | VAF 246/911 reads (27%) | catalogued as rs1383182850; called by muse, mutect2, varscan2
- CACNA1B | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 56/626 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53133008; called by muse, mutect2
- CAMTA2 | c.3490A>C p.K1164Q | Missense Mutation (SNP) | VAF 54/413 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1380636163; called by muse, mutect2, varscan2
- CD53 | c.29A>C p.K10T | Missense Mutation (SNP) | VAF 61/481 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99602190; called by muse, mutect2, varscan2
- CNTLN | c.950T>G p.L317R | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV52066305; called by muse, mutect2, varscan2
- CRAMP1 | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 85/807 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751080703; called by muse, mutect2, varscan2
- DCAF8L2 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 303/1054 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV70549167; called by muse, mutect2, varscan2
- DUSP10 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 99/614 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs764241442; called by muse, varscan2
- ERFE | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 55/474 reads (12%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs770692551; called by muse, mutect2, varscan2
- ERLEC1 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 106/953 reads (11%) | catalogued as COSV99482907; called by muse, mutect2, varscan2
- HCN1 | c.2318C>T p.A773V | Missense Mutation (SNP) | VAF 188/953 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.644); catalogued as rs1232040161; called by muse, mutect2, varscan2
- IQCF1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 69/591 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs146704652, COSV58823362, COSV58824203; called by muse, mutect2, varscan2
- ITIH6 | c.2728A>C p.S910R | Missense Mutation (SNP) | VAF 144/1134 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54489273, COSV54495560; called by muse, mutect2, varscan2
- LAMP5 | c.830A>C p.K277T | Missense Mutation (SNP) | VAF 65/513 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55718111; called by muse, mutect2, varscan2
- MAPK4 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 75/707 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as rs754605852, COSV68541770; called by muse, mutect2, varscan2
- MYH2 | c.4277G>A p.R1426Q | Missense Mutation (SNP) | VAF 90/646 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs772223576; called by muse, mutect2, varscan2
- MYH8 | c.3389C>T p.A1130V | Missense Mutation (SNP) | VAF 158/507 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV101238063; called by muse, mutect2, varscan2
- MYOF | c.4359G>A p.W1453* | Nonsense Mutation (SNP) | VAF 61/385 reads (16%) | catalogued as rs1187637248; called by muse, mutect2, varscan2
- NACC2 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 121/932 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as rs777924546; called by muse, mutect2, varscan2
- NRG3 | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 140/689 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1022935750, COSV64563764; called by muse, mutect2, varscan2
- NUDT22 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 66/422 reads (16%) | catalogued as rs560431443; called by mutect2, varscan2
- OR5AC2 | c.38A>T p.E13V | Missense Mutation (SNP) | VAF 52/434 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV62279076; called by mutect2, varscan2
- OR8H3 | c.167T>G p.L56R | Missense Mutation (SNP) | VAF 51/492 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100538791, COSV57908101, COSV57910433; called by muse, mutect2, varscan2
- PAPPA2 | c.5323T>C p.C1775R | Missense Mutation (SNP) | VAF 73/511 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV62790397; called by muse, mutect2, varscan2
- PCDH9 | c.3672A>C p.Q1224H (on ENST00000377865 / NM_203487.3; = p.Q1190H on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/482 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as COSV60532342, COSV60570035; called by muse, mutect2, varscan2
- PDZRN4 | c.1799T>G p.L600R (on ENST00000402685 / NM_001164595.2; = p.L342R on NM_013377.4) | Missense Mutation (SNP) | VAF 58/420 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV54196850; called by muse, varscan2
- PHYHIPL | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 35/457 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs749912782, COSV65849642, COSV65849663; called by muse, mutect2
- PITHD1 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 51/402 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.608); catalogued as rs373125988; called by muse, mutect2
- PLIN5 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 237/853 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs369901049; called by muse, mutect2, varscan2
- PRRX1 | c.443A>C p.K148T | Missense Mutation (SNP) | VAF 61/380 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1272026144, COSV53410909, COSV99509643; called by muse, mutect2, varscan2
- PTPRT | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 89/840 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs372070542; called by muse, mutect2, varscan2
- RIMKLB | c.447A>C p.E149D | Missense Mutation (SNP) | VAF 58/406 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV55235750; called by muse, mutect2, varscan2
- ROBO2 | c.1474A>G p.S492G | Missense Mutation (SNP) | VAF 56/332 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs776573854, COSV59899892, COSV59950939; called by muse, mutect2, varscan2
- RUNDC3B | c.848A>C p.K283T | Missense Mutation (SNP) | VAF 31/303 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1036223983; called by muse, mutect2
- SCNN1G | c.1691G>A p.R564H | Missense Mutation (SNP) | VAF 114/774 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs762732326, COSV55597490; called by muse, mutect2, varscan2
- SNX30 | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 148/600 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs372045178; called by muse, mutect2, varscan2
- SPTLC3 | c.1250T>C p.L417P | Missense Mutation (SNP) | VAF 49/473 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV65463363; called by muse, mutect2, varscan2
- ST6GAL2 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 239/1015 reads (24%) | PolyPhen possibly damaging (0.849); catalogued as rs1178047224, COSV64526876; called by muse, mutect2, varscan2
- SUSD5 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 31/233 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1281714884; called by muse, mutect2, varscan2
- SYN1 | c.1408C>A p.P470T | Missense Mutation (SNP) | VAF 77/556 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV55980943; called by muse, mutect2, varscan2
- TBR1 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 121/1012 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.029); catalogued as COSV101271574; called by muse, mutect2, varscan2
- TLR4 | c.304A>C p.S102R (on ENST00000355622 / NM_138554.5; = p.S62R on NM_003266.4) | Missense Mutation (SNP) | VAF 71/539 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV62923942; called by muse, mutect2, varscan2
- TMOD3 | c.282dup p.G95Rfs*22 | Frame Shift Ins (INS) | VAF 46/292 reads (16%) | catalogued as rs759399045; called by mutect2, varscan2
- TRIM49B | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 85/689 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1227719531; called by muse, mutect2, varscan2
- TUBA4B | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 62/489 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.035); catalogued as rs558404074, COSV67525187; called by muse, mutect2, varscan2
- TUBB6 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 176/685 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.924); catalogued as rs1204760194; called by muse, mutect2, varscan2
- ZNF79 | c.218G>A p.S73N | Missense Mutation (SNP) | VAF 115/532 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780098869; called by muse, mutect2
- ZNF99 | c.2004A>C p.K668N | Missense Mutation (SNP) | VAF 72/446 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV68055472; called by muse, mutect2, varscan2
- ZPR1 | c.318_321del p.V107Gfs*6 | Frame Shift Del (DEL) | VAF 158/530 reads (30%) | catalogued as rs780692981; called by pindel, varscan2
- ABCB7 | c.104G>C p.S35T | Missense Mutation (SNP) | VAF 233/955 reads (24%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACTL7A | c.650T>C p.V217A | Missense Mutation (SNP) | VAF 152/666 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ADAMTS3 | c.2098G>A p.D700N | Missense Mutation (SNP) | VAF 83/307 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRE5 | c.1514G>A p.G505E (on ENST00000242786 / NM_078481.4; = p.G412E on NM_001784.5) | Missense Mutation (SNP) | VAF 117/852 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- ADGRV1 | c.4196A>G p.H1399R | Missense Mutation (SNP) | VAF 109/551 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- ALPK1 | c.1135A>C p.S379R | Missense Mutation (SNP) | VAF 92/553 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASH1L | c.6310G>A p.D2104N (on ENST00000368346 / NM_001366177.2; = p.D2099N on NM_018489.3) | Missense Mutation (SNP) | VAF 60/388 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTBD1 | c.929A>G p.N310S | Missense Mutation (SNP) | VAF 64/494 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- CAMSAP1 | c.4009C>T p.R1337C | Missense Mutation (SNP) | VAF 158/610 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- CAPG | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 92/878 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLEC3A | c.446A>G p.K149R (on ENST00000651443; = p.K140R on NM_005752.6) | Missense Mutation (SNP) | VAF 78/655 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, varscan2
- CLSPN | c.477dup p.G160Rfs*15 | Frame Shift Ins (INS) | VAF 38/326 reads (12%) | called by mutect2, pindel, varscan2
- CNTLN | c.4071A>C p.E1357D | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- CNTN5 | c.2036T>G p.V679G | Missense Mutation (SNP) | VAF 73/616 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTNAP2 | c.2849A>C p.E950A | Missense Mutation (SNP) | VAF 188/899 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- COX10 | c.443T>C p.L148P | Missense Mutation (SNP) | VAF 49/359 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CREB3L4 | c.738G>C p.E246D | Missense Mutation (SNP) | VAF 72/498 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYRIA | c.679A>C p.T227P | Missense Mutation (SNP) | VAF 57/479 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- DBP | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 329/1027 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- DNAH3 | c.2324T>C p.L775P | Missense Mutation (SNP) | VAF 70/451 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- FAM89A | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 92/940 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2
- FKBP1C | c.143A>C p.K48T | Missense Mutation (SNP) | VAF 120/767 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- FLT3LG | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 82/679 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GLS2 | c.1511G>T p.R504M | Missense Mutation (SNP) | VAF 93/343 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GMNC | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 91/393 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- GPS1 | c.176_208del p.R59_T69del | In Frame Del (DEL) | VAF 86/765 reads (11%) | called by mutect2, pindel
- GPSM2 | c.351T>G p.N117K | Missense Mutation (SNP) | VAF 124/560 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- HCST | c.125G>T p.C42F | Missense Mutation (SNP) | VAF 226/688 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HELB | c.193del p.I65Ffs*18 | Frame Shift Del (DEL) | VAF 34/259 reads (13%) | called by mutect2, pindel, varscan2
- IGSF1 | c.1397A>G p.N466S | Missense Mutation (SNP) | VAF 225/1030 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- KCNQ3 | c.1494A>C p.E498D | Missense Mutation (SNP) | VAF 77/539 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.058); called by mutect2, varscan2
- KIAA1841 | c.1569G>T p.E523D | Missense Mutation (SNP) | VAF 48/450 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.222); called by mutect2, varscan2
- KLF18 | c.2578A>G p.N860D | Missense Mutation (SNP) | VAF 88/757 reads (12%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- KLHL13 | c.1502T>G p.F501C | Missense Mutation (SNP) | VAF 38/426 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2
- LONRF3 | c.1190A>G p.E397G (on ENST00000371628 / NM_001031855.3; = p.E356G on NM_024778.5) | Missense Mutation (SNP) | VAF 137/1247 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRK2 | c.2620G>T p.E874* | Nonsense Mutation (SNP) | VAF 53/431 reads (12%) | called by muse, mutect2, varscan2
- NEGR1 | c.226A>C p.S76R | Missense Mutation (SNP) | VAF 83/555 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- OR2T33 | c.956_959delinsAAA p.S319* | Nonsense Mutation (DEL) | VAF 53/436 reads (12%) | called by pindel, varscan2*
- PCDH15 | c.3130C>T p.P1044S | Missense Mutation (SNP) | VAF 51/404 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- PCSK1N | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 158/1270 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PHLDB1 | c.2137G>A p.V713M | Missense Mutation (SNP) | VAF 221/748 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PLEKHG7 | c.1960A>C p.N654H | Missense Mutation (SNP) | VAF 31/280 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- POC5 | c.437T>G p.V146G (on ENST00000428202 / NM_001099271.2; = p.V121G on NM_152408.2) | Missense Mutation (SNP) | VAF 87/573 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PPIE | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 108/667 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, varscan2
- RAB11FIP3 | c.715-1G>A p.X239_splice | Splice Site (SNP) | VAF 28/732 reads (4%) | called by muse, mutect2
- RETREG3 | c.585G>C p.L195F | Missense Mutation (SNP) | VAF 129/601 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ROBO1 | c.381_382insG p.F128Vfs*12 | Frame Shift Ins (INS) | VAF 60/529 reads (11%) | called by mutect2, pindel, varscan2
- SETSIP | c.635T>A p.F212Y | Missense Mutation (SNP) | VAF 108/662 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SLC25A13 | c.1226T>G p.L409R | Missense Mutation (SNP) | VAF 50/434 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- SLC35A2 | c.755G>A p.W252* | Nonsense Mutation (SNP) | VAF 121/1144 reads (11%) | called by muse, mutect2, varscan2
- SLC39A12 | c.1284T>G p.H428Q | Missense Mutation (SNP) | VAF 43/345 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC8A1 | c.599A>T p.H200L | Missense Mutation (SNP) | VAF 22/681 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLITRK2 | c.1373T>A p.V458D | Missense Mutation (SNP) | VAF 80/833 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); called by muse, mutect2
- SSX2IP | c.1198C>G p.Q400E | Missense Mutation (SNP) | VAF 42/354 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SZT2 | c.6871G>C p.G2291R (on ENST00000634258 / NM_001365999.1; = p.G2234R on NM_015284.4) | Missense Mutation (SNP) | VAF 51/372 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THOC1 | c.1973A>T p.*658Lext*11 | Nonstop Mutation (SNP) | VAF 25/221 reads (11%) | called by muse, mutect2, varscan2
- TIGD7 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 61/560 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TMED1 | c.80del p.P27Rfs*36 | Frame Shift Del (DEL) | VAF 116/882 reads (13%) | called by pindel, varscan2
- TMEM143 | c.146C>G p.A49G | Missense Mutation (SNP) | VAF 137/983 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TSSK4 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 38/555 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2
- TUT7 | c.3703G>C p.G1235R | Missense Mutation (SNP) | VAF 116/464 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBR4 | c.5263C>G p.L1755V | Missense Mutation (SNP) | VAF 72/504 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- USH2A | c.3939T>G p.N1313K | Missense Mutation (SNP) | VAF 90/600 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- ZC3H12D | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 103/691 reads (15%) | called by muse, mutect2, varscan2
- ZNF287 | c.1738A>T p.I580F | Missense Mutation (SNP) | VAF 58/521 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2
- ZNF668 | c.686G>A p.C229Y | Missense Mutation (SNP) | VAF 76/640 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF713 | c.371G>A p.S124N (on ENST00000633730 / NM_001366796.2; = p.S137N on NM_182633.3) | Missense Mutation (SNP) | VAF 60/627 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ABHD6 | c.999C>T p.N333= | Silent (SNP) | VAF 43/402 reads (11%) | catalogued as COSV55910368; called by muse, mutect2, varscan2
- APOBEC3H | c.297C>T p.H99= | Silent (SNP) | VAF 162/830 reads (20%) | catalogued as rs766306762, COSV62378591; called by muse, mutect2
- ASB7 | c.468C>T p.L156= | Silent (SNP) | VAF 110/701 reads (16%) | catalogued as rs549056141; called by muse, mutect2, varscan2
- CACNA1S | c.2013T>G p.T671= | Silent (SNP) | VAF 87/628 reads (14%) | catalogued as COSV62938202; called by muse, mutect2, varscan2
- CDH13 | c.309G>A p.A103= | Silent (SNP) | VAF 78/752 reads (10%) | catalogued as rs751351911; called by muse, mutect2, varscan2
- CNNM1 | c.189C>T p.R63= | Silent (SNP) | VAF 52/1296 reads (4%) | called by muse, mutect2
- COL6A6 | c.1632G>C p.L544= | Silent (SNP) | VAF 87/762 reads (11%) | catalogued as rs1430010163; called by muse, mutect2, varscan2
- DPP3 | c.36C>T p.I12= | Silent (SNP) | VAF 75/557 reads (13%) | catalogued as rs199628557, COSV100291712; called by muse, mutect2, varscan2
- EXOC7 | c.477G>A p.T159= | Silent (SNP) | VAF 40/612 reads (7%) | catalogued as rs200511065; called by muse, mutect2
- H2BC4 | c.363G>A p.K121= | Silent (SNP) | VAF 77/582 reads (13%) | catalogued as COSV100019812; called by muse, mutect2, varscan2
- IGF2R | c.5136G>A p.V1712= | Silent (SNP) | VAF 68/510 reads (13%) | called by muse, mutect2, varscan2
- KCNV1 | c.814A>C p.R272= | Silent (SNP) | VAF 84/728 reads (12%) | catalogued as COSV52089305; called by muse, mutect2, varscan2
- KIAA0825 | c.3549A>G p.E1183= | Silent (SNP) | VAF 108/448 reads (24%) | catalogued as rs1173822168; called by muse, mutect2, varscan2
- KIAA1841 | c.591C>T p.D197= | Silent (SNP) | VAF 54/529 reads (10%) | catalogued as rs756973200, COSV99693666; called by muse, mutect2, varscan2
- LAMP2 | c.276C>T p.F92= | Silent (SNP) | VAF 99/1040 reads (10%) | catalogued as rs754577706; ClinVar: likely benign; called by muse, mutect2
- LCAT | c.480C>T p.D160= | Silent (SNP) | VAF 99/775 reads (13%) | catalogued as rs773888164, COSV50453551; called by muse, mutect2, varscan2
- MED24 | c.1032C>A p.L344= | Silent (SNP) | VAF 114/1531 reads (7%) | called by muse, mutect2
- MEGF8 | c.5727C>T p.G1909= (on ENST00000251268 / NM_001271938.2; = p.G1842= on NM_001410.3) | Silent (SNP) | VAF 85/720 reads (12%) | catalogued as rs1487904074; called by muse, mutect2, varscan2
- MST1 | c.1239G>A p.P413= | Silent (SNP) | VAF 66/508 reads (13%) | catalogued as COSV56533546, COSV56534356; called by muse, mutect2, varscan2
- MYO16 | c.4089C>T p.Y1363= | Silent (SNP) | VAF 130/945 reads (14%) | catalogued as COSV62762279; called by muse, mutect2, varscan2
- MYO5B | c.5307C>G p.T1769= | Silent (SNP) | VAF 46/357 reads (13%) | called by muse, mutect2, varscan2
- NACC2 | c.615G>A p.A205= | Silent (SNP) | VAF 124/1057 reads (12%) | catalogued as rs1386787122; called by muse, mutect2, varscan2
- PNPLA7 | c.1374C>T p.D458= | Silent (SNP) | VAF 68/680 reads (10%) | called by muse, mutect2
- PPIG | c.1230G>A p.R410= | Silent (SNP) | VAF 26/211 reads (12%) | called by muse, mutect2, varscan2
- PPP4R4 | c.234C>A p.L78= | Silent (SNP) | VAF 74/551 reads (13%) | catalogued as COSV58555072; called by muse, mutect2, varscan2
- PRRT1B | c.396G>A p.A132= | Silent (SNP) | VAF 126/906 reads (14%) | called by muse, mutect2, varscan2
- RFPL3 | c.276C>T p.P92= (on ENST00000249007 / NM_001098535.1; = p.P63= on NM_006604.2) | Silent (SNP) | VAF 75/900 reads (8%) | catalogued as rs1424087160; called by muse, mutect2
- RIMS1 | c.5001C>T p.P1667= | Silent (SNP) | VAF 78/574 reads (14%) | called by muse, mutect2, varscan2
- SEMA4C | c.1452C>G p.L484= | Silent (SNP) | VAF 61/560 reads (11%) | catalogued as COSV100560857; called by muse, mutect2, varscan2
- SIKE1 | c.18G>A p.E6= | Silent (SNP) | VAF 62/529 reads (12%) | called by muse, mutect2, varscan2
- SLC18B1 | c.159A>T p.I53= | Silent (SNP) | VAF 58/396 reads (15%) | called by muse, varscan2
- SLC4A5 | c.1908C>T p.T636= | Silent (SNP) | VAF 206/793 reads (26%) | catalogued as rs759680827, COSV61030271; called by muse, mutect2, varscan2
- SLITRK5 | c.2748C>G p.L916= | Silent (SNP) | VAF 211/857 reads (25%) | catalogued as COSV61522192; called by muse, mutect2, varscan2
- TBC1D3L | c.1503G>A p.R501= | Silent (SNP) | VAF 238/912 reads (26%) | called by muse, mutect2, varscan2
- TDRD12 | c.2235C>T p.T745= | Silent (SNP) | VAF 316/856 reads (37%) | catalogued as rs754001972; called by muse, mutect2, varscan2
- TEX13B | c.708C>T p.C236= | Silent (SNP) | VAF 117/1009 reads (12%) | catalogued as rs41300888; called by muse, mutect2, varscan2
- TRIM72 | c.1107C>T p.R369= | Silent (SNP) | VAF 311/1099 reads (28%) | called by muse, mutect2, varscan2
- ZIC4 | c.654A>G p.S218= | Silent (SNP) | VAF 61/478 reads (13%) | catalogued as rs1354831673, COSV67171032; called by muse, mutect2, varscan2
- ZNF438 | c.2382C>T p.H794= | Silent (SNP) | VAF 85/769 reads (11%) | called by muse, mutect2, varscan2
- AC244197.3 | c.*2326C>T | 3'UTR (SNP) | VAF 50/449 reads (11%) | called by muse, mutect2, varscan2
- AGAP2 | chr12:57741919 G>A | 5'Flank (SNP) | VAF 3413/3899 reads (88%) | called by muse, mutect2, varscan2
- ATXN8OS | n.499+1017G>T | Intron (SNP) | VAF 104/349 reads (30%) | called by mutect2, varscan2
- ATXN8OS | n.499+1180A>C | Intron (SNP) | VAF 64/396 reads (16%) | called by muse, mutect2, varscan2
- CCL14 | c.80-48G>A | Intron (SNP) | VAF 113/812 reads (14%) | called by muse, mutect2, varscan2
- DCHS2 | n.1514A>T | RNA (SNP) | VAF 113/721 reads (16%) | called by muse, mutect2, varscan2
- LINC01278 | n.545A>C | RNA (SNP) | VAF 66/443 reads (15%) | called by muse, mutect2, varscan2
- RAB30 | chr11:83072142 T>C | 5'Flank (SNP) | VAF 68/915 reads (7%) | called by muse, mutect2
- TTN | c.10361-4848G>A | Intron (SNP) | VAF 31/299 reads (10%) | called by muse, mutect2, varscan2
